Somatic mutation profile of tumor specimen TCGA-DX-AB2G-01A (aliquot TCGA-DX-AB2G-01A-11D-A38Z-09) from TCGA case TCGA-DX-AB2G, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 36.2 years (13,239 days).
Specimen TCGA-DX-AB2G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b48b4aa-7b2f-45a8-bb03-1db7074660e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB2G-10A (Blood Derived Normal), aliquot TCGA-DX-AB2G-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4d91510-046d-4f91-83b8-a0f84984948e

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 6, Frame Shift Del 1, Frame Shift Ins 1, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSBG1 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99356924; called by muse, mutect2, varscan2
- B4GALNT1 | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 34/697 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145474220; called by muse, mutect2
- CFAP46 | c.6055G>A p.E2019K | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV99583769; called by muse, mutect2, varscan2
- DISP3 | c.3757G>A p.V1253I | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs200620988; called by muse, mutect2, varscan2
- DNAH9 | c.8851G>T p.V2951L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV99303240; called by muse, mutect2, varscan2
- ELL2 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs750469219, COSV99427101; called by muse, mutect2, varscan2
- EPG5 | c.7726G>C p.D2576H | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.234); catalogued as COSV99956286; called by muse, mutect2, varscan2
- FBXO5 | c.1291A>G p.I431V | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99999618; called by muse, mutect2
- GPRASP2 | c.226A>T p.T76S | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.34); PolyPhen benign (0.13); catalogued as COSV100176492; called by muse, mutect2, varscan2
- GRIN2A | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV100410155, COSV58027171; called by muse, mutect2, varscan2
- HCN1 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs370113959; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KIAA1217 | c.4774G>A p.G1592R | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750604169, COSV56812432; called by muse, mutect2, varscan2
- LRP1 | c.8455G>A p.D2819N | Missense Mutation (SNP) | VAF 16/502 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.396); catalogued as COSV99673963; called by muse, mutect2
- MPO | c.2238G>T p.*746Yext*9 | Nonstop Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV51862444, COSV99228229; called by muse, mutect2, varscan2
- MROH2B | c.2906G>A p.R969K | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV101270432, COSV68189609; called by muse, mutect2, varscan2
- OR5J2 | c.566G>A p.C189Y | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369709977, COSV100398865; called by muse, mutect2, varscan2
- PEG3 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99686746; called by muse, mutect2, varscan2
- SDR39U1 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1193102222, COSV99249260; called by muse, mutect2, varscan2
- SRRM4 | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV99937514; called by muse, mutect2, varscan2
- TAF6 | c.1604C>A p.P535Q | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.278); catalogued as COSV100612580; called by muse, mutect2
- TCHHL1 | c.2170C>A p.L724I | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV100916491; called by muse, mutect2, varscan2
- THBS3 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.613); catalogued as rs779861825, COSV100366692; called by muse, mutect2, varscan2
- TRMT9B | c.1208T>C p.L403S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as rs1461915577, COSV101501502; called by muse, mutect2, varscan2
- ZNF280A | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as COSV100130912, COSV100131304; called by muse, mutect2, varscan2
- KLF6 | c.286dup p.C96Lfs*19 | Frame Shift Ins (INS) | VAF 23/52 reads (44%) | called by mutect2, pindel, varscan2
- RIC1 | c.4136del p.G1379Afs*58 | Frame Shift Del (DEL) | VAF 30/75 reads (40%) | called by mutect2, pindel, varscan2
- SLC25A17 | c.913C>A p.H305N | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); called by muse, mutect2
- BEST3 | c.756G>T p.L252= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as COSV100437492, COSV58307062; called by muse, mutect2, varscan2
- FHDC1 | c.2808T>C p.D936= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99470943; called by muse, mutect2, varscan2
- FOXS1 | c.546T>C p.T182= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs369259178, COSV99639377; called by muse, mutect2, varscan2
- PRKCB | c.1413C>T p.N471= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as rs745373140, COSV100331820; called by muse, mutect2, varscan2
- SELP | c.393C>T p.C131= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as rs374152128, COSV55249264; called by muse, mutect2, varscan2
- STYXL2 | c.2895G>T p.S965= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV99608401; called by muse, mutect2, varscan2
- CTBP2 | c.58+12128G>T | Intron (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100456029; called by muse, mutect2, varscan2
